Somatic mutation profile of tumor specimen TCGA-56-8503-01A (aliquot TCGA-56-8503-01A-11D-2395-08) from TCGA case TCGA-56-8503, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 76.9 years (28,095 days).
Specimen TCGA-56-8503-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d8b6ee1-e4af-4ec9-908e-912a1c79a423.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-56-8503-10A (Blood Derived Normal), aliquot TCGA-56-8503-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a799594-aca7-4752-b3fd-204290aecd2f

The open-access MAF lists 179 somatic variants for this specimen: 136 protein-altering or splice-affecting, 36 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 116, Silent 36, Nonsense Mutation 9, Splice Site 6, Intron 5, Frame Shift Del 4, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1245_1248del p.D415Efs*20 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs80338965; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- TP53 | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 7/54 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AADACL4 | c.1081G>A p.E361K | Missense Mutation (SNP) | VAF 11/207 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV100879453; called by muse, mutect2
- ABCB5 | c.3632C>T p.T1211I (on ENST00000404938 / NM_001163941.2; = p.T766I on NM_178559.6) | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.139); catalogued as COSV99328929; called by muse, mutect2, varscan2
- ACACB | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 8/184 reads (4%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1449416193, COSV100623089; called by muse, mutect2
- ADAMTS5 | c.2255C>G p.P752R | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99537952; called by muse, mutect2, varscan2
- ADAMTS5 | c.2254C>A p.P752T | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99537957; called by muse, mutect2, varscan2
- ADGRG4 | c.9153C>G p.F3051L | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99796044; called by muse, mutect2
- ALX1 | c.581G>A p.G194D | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100374508, COSV57492277; called by muse, mutect2
- AMER3 | c.94G>T p.E32* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100366716; called by muse, mutect2
- AP2M1 | c.1174-2A>G p.X392_splice | Splice Site (SNP) | VAF 16/194 reads (8%) | catalogued as COSV99490307; called by muse, mutect2
- AQR | c.2711G>A p.R904Q | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.133); catalogued as rs1158075610, COSV50041236; called by muse, mutect2
- ARHGEF18 | c.3233C>G p.S1078C (on ENST00000359920 / NM_001130955.2; = p.S974C on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.176); catalogued as COSV100149750, COSV60467359; called by muse, mutect2, varscan2
- AUTS2 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100718516; called by muse, mutect2, varscan2
- BAG2 | c.148G>T p.E50* | Nonsense Mutation (SNP) | VAF 11/110 reads (10%) | catalogued as COSV100857782; called by muse, mutect2
- BPIFB1 | c.1441C>T p.P481S | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.047); catalogued as COSV99487502; called by muse, mutect2, varscan2
- C22orf23 | c.457C>A p.P153T | Missense Mutation (SNP) | VAF 10/203 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as COSV99317430; called by muse, mutect2
- CCDC30 | c.1550C>G p.S517C (on ENST00000340612; = p.S474C on NM_001080850.3) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.212); catalogued as COSV100501501; called by muse, mutect2, varscan2
- CDH18 | c.961G>T p.D321Y | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99936649; called by muse, mutect2, varscan2
- CFAP91 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99847303; called by muse, mutect2, varscan2
- CIAO1 | c.288+1G>T p.X96_splice | Splice Site (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99302678; called by muse, mutect2, varscan2
- CLIP1 | c.3763G>C p.E1255Q (on ENST00000620786 / NM_001247997.1; = p.E1244Q on NM_002956.2) | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100212059, COSV56796675; called by muse, mutect2
- COL9A1 | c.1065A>G p.P355= | Splice Region (SNP) | VAF 4/36 reads (11%) | catalogued as rs1478162361, COSV100295147, COSV57882640; called by muse, mutect2
- COL9A1 | c.1063C>A p.P355T | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV100295149; called by muse, mutect2
- CSMD2 | c.4082A>T p.Q1361L | Missense Mutation (SNP) | VAF 23/189 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV99592407; called by muse, mutect2, varscan2
- CSMD3 | c.7097C>G p.S2366* (on ENST00000297405 / NM_001363185.1; = p.S2262* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 4/64 reads (6%) | catalogued as COSV99840017; called by muse, mutect2
- DCAF8L1 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.418); catalogued as COSV101491498; called by muse, mutect2, varscan2
- DENND3 | c.895A>G p.T299A | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99371273; called by muse, mutect2, varscan2
- DHX30 | c.2161C>A p.P721T (on ENST00000445061 / NM_138615.3; = p.P682T on NM_014966.3) | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99275782; called by muse, mutect2, varscan2
- DST | c.12602T>C p.I4201T (on ENST00000361203 / NM_001374722.1; = p.I1789T on NM_015548.5) | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as COSV99758089; called by muse, mutect2
- DVL3 | c.672G>C p.Q224H | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.365); catalogued as COSV100493726; called by muse, mutect2, varscan2
- ESRRG | c.334C>T p.P112S | Missense Mutation (SNP) | VAF 30/236 reads (13%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100752207, COSV100753411; called by muse, mutect2, varscan2
- EXPH5 | c.5120C>G p.S1707* | Nonsense Mutation (SNP) | VAF 8/224 reads (4%) | catalogued as COSV99761761; called by muse, mutect2
- FAT1 | c.9854G>A p.G3285E | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101499349, COSV71673613; called by muse, mutect2
- FBXL4 | c.513-2A>T p.X171_splice | Splice Site (SNP) | VAF 14/69 reads (20%) | catalogued as COSV100014244; called by muse, mutect2, varscan2
- FMNL3 | c.1604-1G>C p.X535_splice | Splice Site (SNP) | VAF 7/42 reads (17%) | catalogued as COSV99526649; called by muse, mutect2, varscan2
- FOLR2 | c.346C>A p.Q116K | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.388); catalogued as COSV99995497; called by muse, mutect2
- GCN1 | c.4235C>T p.S1412L | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1010571973, COSV56108450; called by muse, mutect2
- GCSAML | c.209C>A p.T70N | Missense Mutation (SNP) | VAF 19/197 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV100825996, COSV63578489; called by muse, mutect2
- GRIA3 | c.186G>T p.Q62H | Missense Mutation (SNP) | VAF 26/123 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV99990903; called by muse, mutect2, varscan2
- HELLS | c.1782G>T p.L594F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99492217; called by muse, mutect2, varscan2
- HELLS | c.1783G>T p.V595L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as COSV99492219; called by muse, mutect2, varscan2
- HLA-DRA | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs770825671, COSV100895037; called by muse, mutect2
- HMCN1 | c.14353G>A p.D4785N | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV99632148; called by muse, mutect2
- HTR7 | c.993C>G p.I331M | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV53285782, COSV99519951; called by muse, mutect2, varscan2
- IFTAP | c.613A>C p.K205Q | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100531234; called by muse, mutect2, varscan2
- IGLV4-60 | c.83C>A p.S28* | Nonsense Mutation (SNP) | VAF 14/134 reads (10%) | catalogued as COSV101135230; called by muse, mutect2
- JAKMIP1 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.395); catalogued as COSV51534178; called by muse, mutect2
- KCNC4 | c.1724G>T p.R575L | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.22); PolyPhen probably damaging (0.982); catalogued as rs761187683, COSV100873654; called by muse, mutect2, varscan2
- KCNH4 | c.2386C>T p.H796Y | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52920213; called by muse, mutect2, varscan2
- KDM2B | c.2335G>C p.D779H | Missense Mutation (SNP) | VAF 18/222 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV100997516; called by muse, mutect2
- KLK3 | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 7/155 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV58099501; called by muse, mutect2
- LATS1 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.656); catalogued as COSV99486328; called by muse, mutect2
- LDB1 | c.785A>G p.Y262C (on ENST00000425280 / NM_001321612.2; = p.Y226C on NM_003893.5) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.952); catalogued as COSV100756424; called by muse, mutect2, varscan2
- MACF1 | c.10977G>C p.L3659F (on ENST00000372915; = p.L1592F on NM_012090.5) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | catalogued as COSV57114590; called by muse, mutect2
- MATN3 | c.1150G>C p.D384H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101337461; called by muse, mutect2
- MMP20 | c.886T>C p.C296R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99497800; called by muse, mutect2, varscan2
- MORC1 | c.2411C>G p.S804C | Missense Mutation (SNP) | VAF 15/150 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); catalogued as rs762537920, COSV99226883; called by muse, mutect2, varscan2
- MYEF2 | c.856G>C p.A286P | Missense Mutation (SNP) | VAF 9/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99981873; called by muse, mutect2
- NAPEPLD | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as COSV100085793; called by muse, mutect2, varscan2
- NAV2 | c.793C>G p.Q265E | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV100586700, COSV62336791; called by muse, mutect2
- NCEH1 | c.331C>G p.Q111E (on ENST00000538775; = p.Q79E on NM_020792.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99860258; called by muse, mutect2, varscan2
- NOC4L | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV100223127; called by muse, mutect2
- NOTCH1 | c.2576C>G p.T859R | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV99489787; called by muse, mutect2
- NPAP1 | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs768411016, COSV100275699; called by muse, mutect2
- NR1H4 | c.250C>A p.P84T (on ENST00000551379 / NM_001206993.2; = p.P74T on NM_005123.4) | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.06); catalogued as rs1235836559, COSV99500867; called by muse, mutect2, varscan2
- NUP133 | c.2981-2A>G p.X994_splice | Splice Site (SNP) | VAF 11/84 reads (13%) | catalogued as COSV99773171; called by muse, mutect2, varscan2
- NUP210L | c.4303G>C p.D1435H | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99668521; called by muse, mutect2
- OAZ1 | c.214C>G p.H72D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV100457369; called by muse, mutect2, varscan2
- OLFML2B | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs575795425, COSV54196325, COSV54196652; called by muse, mutect2
- OR1C1 | c.187C>T p.L63F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68715595; called by muse, mutect2, varscan2
- OR2T4 | c.41C>A p.S14* | Nonsense Mutation (SNP) | VAF 16/99 reads (16%) | catalogued as COSV63545295; called by muse, mutect2, varscan2
- OR5A1 | c.543C>G p.F181L | Missense Mutation (SNP) | VAF 48/430 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100118428; called by muse, mutect2, varscan2
- PAEP | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.43); PolyPhen benign (0.388); catalogued as COSV99478964; called by muse, mutect2, varscan2
- PCARE | c.3515G>C p.R1172T | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100527712; called by muse, mutect2
- PCDH7 | c.2531C>G p.S844C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV100687583, COSV100688503; called by muse, mutect2, varscan2
- PCDHA7 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 20/244 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.341); catalogued as COSV100971630; called by muse, mutect2
- PCDHGA2 | c.2230G>C p.D744H | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.491); catalogued as COSV99542149; called by muse, mutect2
- PDE6C | c.1745G>A p.R582K | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101008803; called by muse, mutect2, varscan2
- PEG3 | c.1307C>A p.S436Y | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.365); catalogued as COSV99689595; called by muse, mutect2, varscan2
- PEX5L | c.395C>G p.S132* | Nonsense Mutation (SNP) | VAF 7/149 reads (5%) | catalogued as COSV55856230; called by muse, mutect2
- PHF14 | c.2663C>A p.S888* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV101301829; called by muse, mutect2, varscan2
- PLXNA4 | c.3014T>C p.V1005A | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.259); catalogued as COSV100325571, COSV58160550; called by muse, mutect2, varscan2
- PPP1R10 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 22/383 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.155); catalogued as rs1470298322, COSV64740258; called by muse, mutect2
- PRDM9 | c.983A>C p.Q328P | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV99690742; called by muse, mutect2, varscan2
- PSTK | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 10/105 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100924787; called by muse, mutect2
- RBM45 | c.135C>G p.F45L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as COSV99617821; called by muse, mutect2
- RESF1 | c.5137G>C p.E1713Q | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV57019740; called by muse, mutect2
- REV3L | c.5450C>G p.S1817C | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1274909037, COSV100725411; called by muse, mutect2, varscan2
- RFX6 | c.1845C>A p.H615Q | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as COSV100263956, COSV60586171; called by muse, mutect2
- RMDN3 | c.671C>G p.S224C | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.151); catalogued as COSV99540147; called by muse, mutect2
- RNF135 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100104151; called by muse, mutect2
- RSAD2 | c.791G>C p.R264T | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs764457341, COSV101149977; called by muse, mutect2
- SCN2A | c.4662C>G p.D1554E | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.314); catalogued as COSV99332462; called by muse, mutect2, varscan2
- SCN9A | c.4184G>C p.G1395A (on ENST00000303354; = p.G1384A on NM_002977.3) | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV100313471; called by muse, mutect2, varscan2
- SCRIB | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 11/156 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.138); catalogued as COSV57582865; called by muse, mutect2
- SERPINA4 | c.55C>G p.H19D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100097327, COSV54070830; called by muse, mutect2
- SFPQ | c.1729G>C p.E577Q | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV100599467; called by muse, mutect2
- SH3GL2 | c.323G>A p.C108Y | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV101014599; called by muse, mutect2, varscan2
- SLC44A3 | c.1171A>G p.S391G (on ENST00000271227 / NM_001114106.3; = p.S343G on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as rs367997467; called by muse, mutect2, varscan2
- SLC4A7 | c.3517G>A p.E1173K | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99840053; called by muse, mutect2, varscan2
- SLC9A2 | c.2018A>G p.N673S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.675); catalogued as rs776012445, COSV99296487; called by muse, mutect2, varscan2
- SLITRK3 | c.2131G>C p.D711H | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99578441, COSV99579619; called by muse, mutect2, varscan2
- SNAPC2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99564224; called by muse, mutect2, varscan2
- SPAG6 | c.466A>T p.N156Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100510374, COSV57620233; called by muse, mutect2, varscan2
- SSH2 | c.2890C>G p.H964D | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.003); catalogued as COSV52172306, COSV99282526; called by muse, mutect2, varscan2
- SSH3 | c.1386C>G p.I462M | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV100354667; called by muse, varscan2
- SSMEM1 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99927708; called by muse, mutect2
- STMN4 | c.277G>A p.E93K (on ENST00000265770 / NM_001283054.2; = p.E120K on NM_030795.4) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99741015; called by muse, mutect2
- SUCLA2 | c.535-2A>T p.X179_splice | Splice Site (SNP) | VAF 13/79 reads (16%) | catalogued as COSV101074897; called by muse, mutect2, varscan2
- SYT13 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs757281112, COSV99074635; called by muse, mutect2, varscan2
- TAB1 | c.1406C>T p.S469L | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs776068209, COSV99336180; called by muse, mutect2, varscan2
- TEAD2 | c.1199A>T p.N400I | Missense Mutation (SNP) | VAF 17/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100115071; called by muse, mutect2, varscan2
- TLR1 | c.1421A>T p.N474I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100458602; called by muse, mutect2, varscan2
- TMEM132D | c.2404G>T p.A802S | Missense Mutation (SNP) | VAF 13/157 reads (8%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.647); catalogued as COSV101242973; called by muse, mutect2
- TPTE | c.161C>T p.P54L | Missense Mutation (SNP) | VAF 17/213 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as rs1380800742; called by muse, mutect2
- TSPO2 | c.179C>A p.A60D | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV55111254, COSV99770900; called by muse, mutect2
- TSR3 | c.802G>A p.E268K | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.473); catalogued as COSV50105365, COSV99136301; called by muse, mutect2
- TTK | c.2066A>G p.Y689C | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771241505, COSV100036443; called by muse, mutect2, varscan2
- UNC93A | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 11/151 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs1309912451, COSV100023464; called by muse, mutect2
- USB1 | c.375G>C p.Q125H | Missense Mutation (SNP) | VAF 8/144 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as COSV99540323; called by muse, mutect2
- USF3 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 15/200 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV100325534; called by muse, mutect2
- ZBED9 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.932); catalogued as COSV101509332; called by muse, mutect2
- ZC3H8 | c.439A>G p.K147E | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as COSV99735570; called by muse, mutect2
- ZNF43 | c.1180G>A p.E394K | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV100731882; called by muse, mutect2, varscan2
- ZNF600 | c.1844G>A p.C615Y | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100593031; called by muse, mutect2, varscan2
- ZNF804A | c.2453G>T p.R818I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV100168943, COSV56467993; called by muse, mutect2, varscan2
- CPSF3 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); called by muse, mutect2
- FAM171B | c.835_838del p.R279* | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, pindel
- NSD1 | c.7277C>G p.S2426* | Nonsense Mutation (SNP) | VAF 5/130 reads (4%) | called by muse, mutect2
- NUP93 | c.769C>G p.Q257E | Missense Mutation (SNP) | VAF 5/147 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2
- PCDHB9 | c.2044C>A p.Q682K | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.067); called by muse, mutect2
- PLD2 | c.225_226del p.T76Qfs*77 | Frame Shift Del (DEL) | VAF 20/162 reads (12%) | called by pindel, varscan2
- RASGRP1 | c.278A>T p.H93L | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2
- SETBP1 | c.1151_1184del p.R384Mfs*49 | Frame Shift Del (DEL) | VAF 9/115 reads (8%) | called by mutect2, pindel
- TREM2 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- AEBP1 | c.2535C>T p.I845= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as COSV56257094; called by muse, mutect2
- AOC1 | c.963C>A p.G321= | Silent (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- ASH2L | c.1644C>G p.V548= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as COSV99167010; called by muse, mutect2
- C12orf57 | c.33G>A p.L11= | Silent (SNP) | VAF 18/222 reads (8%) | catalogued as rs782168213, COSV57547320; called by muse, mutect2
- CCDC96 | c.1605C>G p.L535= | Silent (SNP) | VAF 7/105 reads (7%) | catalogued as COSV100027997; called by muse, mutect2
- CHST8 | c.1257C>T p.P419= | Silent (SNP) | VAF 5/53 reads (9%) | catalogued as rs760088479, COSV99381334; called by mutect2, varscan2
- CLVS2 | c.60C>G p.L20= | Silent (SNP) | VAF 6/116 reads (5%) | catalogued as COSV99253194; called by muse, mutect2
- CNR1 | c.1002A>G p.Q334= | Silent (SNP) | VAF 8/194 reads (4%) | catalogued as COSV100759379, COSV62990521; called by muse, mutect2
- COPS6 | c.983G>A p.*328= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as COSV100385048; called by muse, mutect2, varscan2
- CSF2RB | c.2469C>T p.C823= | Silent (SNP) | VAF 28/290 reads (10%) | catalogued as COSV99454129; called by muse, mutect2
- CSMD1 | c.9378C>T p.D3126= (on ENST00000520002; = p.D3125= on NM_033225.6) | Silent (SNP) | VAF 27/224 reads (12%) | catalogued as rs750781724, COSV59277498, COSV59301990; called by muse, mutect2, varscan2
- DGCR8 | c.1728C>T p.L576= | Silent (SNP) | VAF 32/234 reads (14%) | catalogued as rs777754452, COSV100708063; called by muse, mutect2, varscan2
- FRMD6 | c.147C>T p.L49= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100656001, COSV61088104; called by muse, mutect2
- GAREM1 | c.1266C>G p.P422= | Silent (SNP) | VAF 8/182 reads (4%) | catalogued as COSV99331000; called by muse, mutect2
- H2AC4 | c.366G>A p.E122= | Silent (SNP) | VAF 7/112 reads (6%) | catalogued as COSV99451596; called by muse, mutect2
- HAVCR1 | c.537G>A p.L179= | Silent (SNP) | VAF 58/858 reads (7%) | catalogued as rs780505150; called by muse, mutect2
- JAKMIP1 | c.276C>A p.I92= | Silent (SNP) | VAF 7/51 reads (14%) | catalogued as COSV99290165; called by muse, mutect2, varscan2
- KIAA0319L | c.1317C>T p.I439= | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as rs749946295, COSV57845918; called by muse, mutect2, varscan2
- KIF4A | c.15G>T p.V5= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV53452380, COSV99516364; called by muse, mutect2, varscan2
- LRRC18 | c.633G>A p.L211= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as rs895745775, COSV99630000; called by muse, mutect2
- MAMLD1 | c.1749A>T p.S583= | Silent (SNP) | VAF 21/169 reads (12%) | catalogued as COSV99476302; called by muse, mutect2, varscan2
- MOG | c.546G>C p.L182= | Silent (SNP) | VAF 8/141 reads (6%) | catalogued as COSV100973065; called by muse, mutect2
- MUC16 | c.7005C>T p.F2335= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs1401652545, COSV67480440; called by muse, mutect2
- NFIL3 | c.666G>A p.P222= | Silent (SNP) | VAF 9/114 reads (8%) | catalogued as rs762664691, COSV99906977; called by muse, mutect2
- NUDT8 | c.514C>T p.L172= | Silent (SNP) | VAF 9/102 reads (9%) | catalogued as COSV100039669, COSV100039842; called by muse, mutect2
- OR2B2 | c.645T>C p.L215= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs767845359, COSV100308178; called by muse, mutect2, varscan2
- PCDHB5 | c.2058T>C p.T686= | Silent (SNP) | VAF 17/271 reads (6%) | catalogued as rs782242118, COSV50660569; called by muse, mutect2
- PPP1R10 | c.111G>A p.L37= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV100919900; called by muse, mutect2, varscan2
- PTCRA | c.373C>T p.L125= | Silent (SNP) | VAF 8/116 reads (7%) | catalogued as COSV100485787; called by muse, mutect2
- PYGL | c.2307T>C p.H769= | Silent (SNP) | VAF 20/202 reads (10%) | catalogued as rs374252511; called by muse, mutect2
- RARB | c.201C>T p.S67= (on ENST00000383772 / NM_001290216.2; = p.S60= on NM_000965.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 17/137 reads (12%) | catalogued as rs1243079579, COSV100412622; called by muse, mutect2, varscan2
- RBBP8NL | c.1089G>A p.Q363= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV99436795; called by muse, mutect2
- SLC7A2 | c.1344G>A p.E448= (on ENST00000494857 / NM_001370338.1; = p.E487= on NM_003046.6) | Silent (SNP) | VAF 13/113 reads (12%) | catalogued as COSV99135232; called by muse, mutect2, varscan2
- SSH3 | c.1338C>G p.L446= | Silent (SNP) | VAF 21/150 reads (14%) | catalogued as COSV100354666; called by muse, varscan2
- TBC1D8 | c.3267A>G p.L1089= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as COSV99961534; called by muse, mutect2
- UFM1 | c.108A>T p.A36= | Silent (SNP) | VAF 24/119 reads (20%) | catalogued as COSV99522660; called by muse, mutect2, varscan2
- AC058822.1 | c.1018-288050C>A | Intron (SNP) | VAF 13/104 reads (13%) | called by muse, mutect2, varscan2
- AL645922.1 | c.256+663G>C | Intron (SNP) | VAF 8/124 reads (6%) | catalogued as COSV100191276; called by muse, mutect2
- BIRC6 | c.12291+688dup | Intron (INS) | VAF 5/46 reads (11%) | called by mutect2, pindel, varscan2
- BMP1 | c.2107+1811C>G | Intron (SNP) | VAF 30/178 reads (17%) | catalogued as COSV100109837, COSV60480382; called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.12G>C | RNA (SNP) | VAF 27/303 reads (9%) | catalogued as rs1234634411; called by muse, mutect2
- MIR527 | n.82G>C | RNA (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- SLC7A2 | c.1195+367T>G | Intron (SNP) | VAF 15/182 reads (8%) | catalogued as COSV99135230; called by muse, mutect2
